CCDI case PBCLXG — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS.
https://portal.gdc.cancer.gov/cases/e0a0da24-356d-4d5e-87c5-7cb76df3dd88

Demographics
Sex at birth: female; Ethnicity: hispanic or latino.

Biospecimens (3 samples)
- Sample 0DVLZD: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DVM1L: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DVM1O: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
